TARGET case TARGET-10-PAKRSL — Acute Lymphoblastic Leukemia - Phase I (TARGET-ALL-P1)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3ee4a9bf-cf89-4c72-a8fe-371c6e9d1910

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 13 years; Vital status: Dead; Days to death: 705 days (1.9 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 13.7 years (5,008 days); Year of diagnosis: 2001; Days to last follow up: 705 days (1.9 years).
   Treatment given: Protocol identifier: P9906.

Follow-up (2 entries)
- Days to follow up: 670 days (1.8 years); Days to first event: 670 days (1.8 years); First event: Relapse.
- Days to follow up: 705 days (1.9 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2003.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 321 ×10³/µL.
- Day 29: Bone Marrow blast count 2%.

Other clinical attributes
- Day 0: Comorbidities: Down Syndrome; Risk factors: Down Syndrome.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 705
- WBC at Diagnosis: 321.2
- CNS Status at Diagnosis: CNS 1
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 29: 2
- Karyotype: 47,XX,+21C[4]/48,IDEM,+X[11]
- Down Syndrome: Yes
- DNA Index: 1
- Cell of Origin: B precursor (Non-T, Non-B ALL)
- ALL Molecular Subtype: None of above

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Xenografts_20230727.xlsx:
- Protocol: 9906
- Cell of Origin: B Cell ALL
